CPTAC case 04OV058 — Other and unspecified female genital organs — Cystic, Mucinous and Serous Neoplasms (CPTAC-2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/0ed2be8e-1d7b-4a08-9740-f642377d58c9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Serous adenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Fallopian tube; FIGO stage: Stage IIIC; Prior malignancy: no.

Biospecimens (2 samples)
- Sample 91b287fd-eadb-442d-abcd-20b741: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample d035cd3d-9ecd-4c59-a1ca-a247fe: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
